Gene-level copy-number profile of specimen HCM-CSHL-0085-C24-85A from HCMI case HCM-CSHL-0085-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.0 years (20,466 days).
Specimen HCM-CSHL-0085-C24-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0beaae1b-02c7-4e26-9c11-c4a0106a534c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0085-C24-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/6273302d-2991-4b62-8275-0014cd43c177

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 511; copy number 1: 1,173; copy number 2: 35,752; copy number 3: 18,219; copy number 4: 3,242; copy number 5: 7; copy number 12: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,085,628–144,373,659, 8 genes, copy number 12: IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr8:67,849,044–67,849,338, 1 gene, copy number 5: NDUFS5P6.
- chr8:94,127,162–94,217,303, 2 genes, copy number 5: CDH17, AP003478.1.
- chr8:107,173,200–107,173,809, 1 gene, copy number 5: HMGB1P46.
- chr8:121,612,116–121,641,440, 1 gene, copy number 5: HAS2.
- chr8:121,668,934–121,697,600, 1 gene, copy number 5: LINC02855.
- chr17:18,432,051–18,442,895, 1 gene, copy number 5: KRT16P1.

Autosomal genes at a single copy (total copy number 1): 298. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
